Surgical pathology report (de-identified scan), TCGA case TCGA-X6-A8C6, project TCGA-SARC (Sarcoma), tissue source site University of Iowa, specimen TCGA-X6-A8C6-01A (Primary Tumor).

[page 1 of 2]
—SURGICAL PATHOLOGY CONSULTATION— (Accession)

Results

Status: Final result

Collection Information

Specimen#	Collection Date	Collection Time	Collected By	Specimen Source	Specimen Description
-----------	-----------------	-----------------	--------------	-----------------	----------------------

Component Results

Component

DIAGNOSIS

- A. Soft tissue, left upper leg mass, resection:
Myxofibrosarcoma/malignant fibrous histiocytoma, 8.5 cm in greatest dimension, with focal extension to the deep margin on the lateral aspect.
All other surgical margins free of tumor.
No vascular or perineural invasion identified.
- B. Soft tissue, left leg extended periosteal margin, excision:
Benign fibromuscular tissue.

Date reported:

Pathologist (Electronic Signature)

HISTORY

Check margins—stitch is proximal.

TISSUE SUBMITTED

- A. Upper Lt leg mass
- B. Extended periosteal margin lt leg mass

FROZEN SECTION

FS:

- A. Upper Lt leg mass: FS: Proximal and distal margins free from tumor. Closest margin is deep margin with tumor <0.1 cm from margin but a tissue plane is present.

GROSS

A. Received fresh for OR consultation in a container labeled with the patient's name, hospital number and "Upper Lt leg mass" is a 670 gram brown portion of muscle oriented with stitch proximal end. The measurements are as follows: Superior to deep 9.0 cm, medial to lateral 10.0 cm, proximal to distal 15.5 cm. Attached to the superficial surface is a tan-pink, smooth skin ellipse, 3.5 x 0.7 cm with no scar identified. Ink identifiers are as follows: Superior proximal is inked blue, superior distal is inked green, medial deep is inked orange and lateral deep is inked black. The specimen is sectioned from proximal to distal to reveal a 6.5 x 8.3 x 6.8 cm lobulated white-tan-yellow mass with minor cystic component. It is 2.2 cm from the proximal margin, 3.0 cm from the distal margin, and <0.1 cm from the deep margin but a plane of tissue is present. A1, perpendicular sections through proximal margin; A2, mass nearest deep margin; A3, mass at superficial margin; A4, mass at medial margin; A5, mass at lateral margin; A6-A7, mass at distal margin; A8, section through skin ellipse underlying tissue to include mass. B. Received in formalin in a container labeled with the patient's name, hospital number and "Extended periosteal margin Lt leg mass" is a 4.1 x 1.3 x 0.9 cm, yellow-pink-red-brown piece of soft tissue with an irregular surface and is focally cauterized. The specimen is sectioned and submitted entirely in B1-B2.

MICROSCOPIC

A. Sections show a proliferation of spindled cells with large, pleomorphic nuclei with fibrous to myxoid background. The mass focally involves the lateral aspect and is located deep to skeletal muscle. Immunoperoxidase stains are negative for S100 and CD57.

Primary Tumor (T)

- X T2b Tumor more than 5 cm identified, deep tumor
- Regional Lymph Nodes (N)

X NX Regional lymph nodes cannot be assessed

The pathologic stage based on available pathologic material is: T2b NX

The optimal block for molecular studies of this neoplasm is: A2.

B. Microscopic examination performed and supports the diagnosis.

Performed by:

As the primary pathologist on this case, I have personally reviewed this case and edited the report as necessary.

INTERNAL CONSULTATION

This case was seen in consultation with

ICD-O-3
Fibromyxosarcoma 8811/3
Site Leg NOS C49.2
JW 11/24/13

[page 2 of 2]
Patient Release Status: _____
This result is viewable by the patient in _____

Last viewed in _____

[REDACTED]

Lab and Collection _____
--SURGICAL PATHOLOGY CONSULTATION-- (Order) _____
- Lab and Collection Information _____

Result History _____
--SURGICAL PATHOLOGY CONSULTATION-- (Order) _____
Order Result History Report _____

Result Entered By _____

Lab Information _____
Lab _____

ok - per BCR lead pathologist 11/4/13 BCR

Source: NCI Genomic Data Commons file 619e4ead-cf70-4dfe-a94f-12e6d4cd3b70 (TCGA-X6-A8C6.D141A308-5AC0-4095-8323-970E0F492660.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).